Gene-level copy-number profile of tumor specimen HCM-CSHL-0512-C24-06A from HCMI case HCM-CSHL-0512-C24, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Ampulla of Vater; AJCC pathologic stage: Stage IIIB; Tumor grade: G3; Age at diagnosis: 76.0 years (27,746 days).
Specimen HCM-CSHL-0512-C24-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 90479368-7e6b-410f-89d8-cc3ddbb1e7b1.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0512-C24-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,218 have no estimate.
https://portal.gdc.cancer.gov/files/cb3297a4-f65c-4c38-9fe5-8e895de0d1ca

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 48; copy number 1: 3; copy number 2: 11,070; copy number 3: 241; copy number 4: 44,990; copy number 5: 860; copy number 6: 538; copy number 7: 131; copy number 8: 86; copy number 9: 58; copy number 10: 51; copy number 11: 21; copy number 12: 88; copy number 13: 10; copy number 14: 28; copy number 15: 11; copy number 16: 5; copy number 18: 8; copy number 19: 75; copy number 21: 7; copy number 26: 27; copy number 27: 5; copy number 31: 10; copy number 36: 8; copy number 43: 26.

Homozygous deletions (total copy number 0; autosomes only): 48 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:25,272,393–25,330,445, 2 genes (within-gene range 0–2): RHD, SDHDP6.
- chr9:61,190,003–61,627,683, 9 genes: SPATA31A7, BX005040.3, BX005040.2, FAM74A4, BX005040.1, CNTNAP3C, RN7SL462P, AL935212.3, FAM242D.
- chr10:87,201,647–88,584,530, 27 genes (within-gene range 0–2): NUTM2A-AS1, AL157893.2, AL157893.1, NUTM2A, LINC00863, NUTM2D, NPAP1P3, CTSLP1, FAM245A, AL355334.1, MINPP1, AL138767.2, AL138767.3, AL138767.1, RPS26P38, PAPSS2, ATAD1, CFL1P1, RN7SL78P, KLLN, PTEN, AC063965.2, RPL11P3, AC063965.1, MED6P1, AL353149.1, RNLS.
- chr18:50,560,087–51,058,144, 10 genes (within-gene range 0–2): MAPK4, AC012433.2, AC012433.1, MRO, HNRNPA3P16, RPL17P46, ME2, Y_RNA, ELAC1, AC091551.1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 438 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:142,666,272–142,667,718, 1 gene, copy number 9: MTRNR2L6.
- chr10:69,180,234–71,302,864, 49 genes, copy number 11–14: SUPV3L1, AL596223.1, HKDC1, AL596223.2, HK1, RPS15AP28, TACR2, ATP5MC1P7, TSPAN15, AC016821.1, TMEM256P1, NEUROG3, AL450311.1, MTATP6P23, MTCO2P23, MTCO1P23, MTND2P15, MTND1P20, FAM241B, LINC02651, RPL5P26, COL13A1, LINC02636, MACROH2A2, AIFM2, TYSND1, SAR1A, CALM2P2, RPS25P9, PPA1, NPFFR1, LRRC20, CEP57L1P1, EIF4EBP2, NODAL, AC022532.1, PALD1, YY1P1, PRF1, ADAMTS14, TBATA, RPS26P40, SGPL1, PCBD1, AC073176.2, AC073176.1, LINC02622, UNC5B, UNC5B-AS1.
- chr12:48,189,349–48,957,487, 46 genes, copy number 9–27 (within-gene range 2–27): AC074029.4, AC024257.3, OR10AD1, AC024257.1, AC024257.5, H1-7, AC024257.2, ZNF641, AC090115.1, OR5BK1P, AC024257.4, OR5BT1P, OR5BJ1P, OR8S21P, OR8T1P, ANP32D, C12orf54, AC089987.2, RPS10P20, AC089987.1, OR8S1, OR5BS1P, LALBA, OR11M1P, KANSL2, SNORA2C, MIR1291, SNORA2A, SNORA2B, CCNT1, TEX49, AC117498.1, ADCY6, MIR4701, ADCY6-DT, AC117498.2, Y_RNA, CACNB3, DDX23, RND1, RNU6-600P, AC073610.1, AC073610.2, CCDC65, FKBP11, ARF3.
- chr12:51,328,442–51,812,864, 7 genes, copy number 12: CELA1, GALNT6, SLC4A8, AC107031.1, SCN8A, HNRNPA3P10, AC068987.1.
- chr12:52,821,408–53,079,404, 12 genes, copy number 12: KRT79, AC107016.1, KRT78, RPL7P41, KRT8, KRT18, EIF4B, AC068888.2, AC068888.1, TNS2, MIR6757, SPRYD3.
- chr12:55,434,734–55,585,471, 2 genes, copy number 12 (within-gene range 6–12): AC122685.1, OR6C2.
- chr12:55,492,378–56,414,045, 76 genes, copy number 12–19 (broad region; genes not listed).
- chr12:57,674,665–58,395,138, 33 genes, copy number 9: RPL13AP23, OS9, AC025165.2, AGAP2, AGAP2-AS1, TSPAN31, CDK4, MIR6759, MARCHF9, CYP27B1, METTL1, EEF1AKMT3, AC025165.3, TSFM, AVIL, AC025165.5, RNU6-1083P, AC025165.4, CTDSP2, MIR26A2, AC083805.2, AC083805.1, AC083805.3, ATP23, GIHCG, AC084033.1, RN7SKP65, AC084033.2, LINC02403, AC090643.1, AC090643.2, RPL21P103, AC025578.1.
- chr12:62,643,994–69,959,097, 170 genes, copy number 10–43 (within-gene range 2–43) (broad region; genes not listed).
- chr12:70,638,073–72,670,758, 27 genes, copy number 12–19: PTPRR, FAHD2P1, Y_RNA, AC123905.1, AC025575.1, AC025575.2, TSPAN8, LGR5, AC090116.1, AC078860.3, ZFC3H1, AC078860.1, THAP2, AC073612.1, TMEM19, AC011601.1, RAB21, AC089984.1, AC089984.2, TBC1D15, MRS2P2, TPH2, AC090109.1, TRHDE, TRHDE-AS1, H3P35, CHCHD3P2.
- chr12:75,020,969–75,390,928, 8 genes, copy number 36: AC073525.1, KCNC2, CAPS2-AS1, CCNG2P1, CAPS2, AC092552.1, AC121761.2, GLIPR1L1.
- chr12:80,707,634–80,937,925, 7 genes, copy number 21 (within-gene range 2–21): MYF6, MYF5, LINC01490, LIN7A, MIR617, AC078886.1, MIR618.

Autosomal genes at a single copy (total copy number 1): 3. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
